Gene-level copy-number profile of tumor specimen TCGA-BA-A4IG-01A from TCGA case TCGA-BA-A4IG, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Oropharynx, NOS; Tumor grade: G3; Age at diagnosis: 77.8 years (28,402 days).
Specimen TCGA-BA-A4IG-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-HNSC.d965b85a-73ff-4909-927a-b47eaa8cd299.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-BA-A4IG-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/9bf36489-c733-4e89-9cdc-ddf964179bb1

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 44; copy number 1: 5; copy number 2: 10,582; copy number 3: 6,482; copy number 4: 33,814; copy number 5: 4,098; copy number 6: 3,334; copy number 7: 641; copy number 8: 795; copy number 9: 24; copy number 12: 1.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-BA-A4IG-01A-11D-A25X-01): tumor purity 0.56, ploidy 1.86, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 44 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:214,697,727–215,138,626, 7 genes: ENSAP3, BARD1, SNHG31, SNORA70I, RPL10P6, ABCA12, AC072062.1.
- chr10:87,642,607–89,017,059, 31 genes (within-gene range 0–2): RPS26P38, PAPSS2, ATAD1, CFL1P1, RN7SL78P, KLLN, PTEN, AC063965.2, RPL11P3, AC063965.1, MED6P1, AL353149.1, RNLS, Y_RNA, LIPJ, RPL7P34, LIPF, NAPGP1, LIPK, KRT8P38, LIPN, RCBTB2P1, LIPM, ANKRD22, PTCD2P2, STAMBPL1, ACTA2-AS1, ACTA2, AL157394.3, FAS, AL157394.2.
- chr15:44,562,696–44,778,721, 6 genes (within-gene range 0–2): SPG11, PATL2, Y_RNA, B2M, TRIM69, AC122108.2.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 25 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:143,265,222–143,848,485, 1 gene, copy number 9 (within-gene range 8–9): SLC9A9.
- chr3:143,620,528–146,606,216, 23 genes, copy number 9: AC073358.1, AC107421.1, DIPK2A, RNA5SP144, AC011592.1, LARP7P4, GM2AP1, RPL21P39, AC055758.2, AC055758.1, AC107021.2, AC107021.1, LNCSRLR, PLOD2, PLSCR4, AC130509.1, AC069528.1, PLSCR2, AC069528.2, PLSCR1, RNU6-428P, PLSCR5, PLSCR5-AS1.
- chr3:189,238,686–189,240,594, 1 gene, copy number 12: TPRG1-AS2.

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
